FM case AD16707 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung.
https://portal.gdc.cancer.gov/cases/e39bb4e1-c2db-4fba-a620-1ab38ec06439

Male, 57.4 years: Squamous cell carcinoma, NOS (ICD-O-3 8070/3) of the lung; primary biopsied or resected from the lung. Tumor nuclei on the sequenced sample's slide: 40% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
